CCDI case PBBXEA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/d06d4642-3531-4875-aea6-db9118efdcff

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Synovial sarcoma, NOS: ICD-O-3 morphology code: 9040/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 22.6 years (8,246 days).

Biospecimens (3 samples)
- Sample 0DLFAW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLFB2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLFBP: Tissue type: Tumor; Specimen type: Solid Tissue.
